Somatic mutation profile of tumor specimen TCGA-06-0939-01A (aliquot TCGA-06-0939-01A-01D-1353-08) from TCGA case TCGA-06-0939, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 79.1 years (28,893 days).
Specimen TCGA-06-0939-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe710170-c3b0-4d8e-b68d-f1443e603e98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0939-10A (Blood Derived Normal), aliquot TCGA-06-0939-10A-01D-1353-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8336c6af-ead1-487d-b435-a03c975da54e

The open-access MAF lists 70 somatic variants for this specimen: 46 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 23, Nonsense Mutation 3, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MMUT | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs564069299, CM990882, COSV51272456, COSV51275106, COSV51281714; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | hotspot (GDC flag); catalogued as rs3092891, CM900192, CX011720, COSV57295313; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.2462C>T p.T821M | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.153); catalogued as rs761160403, COSV52223910; called by muse, mutect2, varscan2
- BDP1 | c.3983C>A p.T1328N | Missense Mutation (SNP) | VAF 78/227 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV62432037; called by muse, mutect2, varscan2
- C11orf65 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs775040844, COSV67597682; called by muse, mutect2, varscan2
- CATSPERD | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.866); catalogued as rs367967767, COSV101062356; called by muse, mutect2, varscan2
- CCDC91 | c.355G>A p.V119M | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.568); catalogued as COSV60343645; called by muse, mutect2, varscan2
- COL20A1 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.348); catalogued as rs1236783690, COSV58919078; called by muse, mutect2, varscan2
- CRYBG1 | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 77/305 reads (25%) | catalogued as rs764916299, COSV64812678; called by muse, mutect2, varscan2
- ENOX2 | c.1808G>T p.G603V (on ENST00000338144 / NM_001382520.1; = p.G574V on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.856); catalogued as COSV57652998; called by muse, mutect2
- ESRRB | c.1205C>T p.T402M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV55062753; called by muse, mutect2, varscan2
- FLG | c.263C>A p.S88Y | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT tolerated (0.78); PolyPhen benign (0.146); catalogued as COSV64243090; called by muse, mutect2, varscan2
- FOXL2NB | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs768279723, COSV57727690; called by muse, mutect2, varscan2
- FOXR2 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.111); catalogued as rs1389430934, COSV59258794; called by muse, mutect2, varscan2
- GUCY1B1 | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as COSV52376356; called by muse, mutect2, varscan2
- HLF | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1329585725, COSV56830449, COSV56830497; called by muse, mutect2, varscan2
- IPO5 | c.401A>T p.K134M | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV55155415; called by muse, mutect2, varscan2
- LAMA3 | c.7297A>G p.N2433D (on ENST00000313654 / NM_198129.4; = p.N824D on NM_000227.6) | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as COSV52536497; called by muse, mutect2, varscan2
- LRP2 | c.1709G>A p.R570H | Missense Mutation (SNP) | VAF 78/286 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770867082, COSV55558005, COSV99787757; called by muse, mutect2, varscan2
- LRRC14 | c.1122G>C p.E374D | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.73); catalogued as rs962717015, COSV52880094; called by muse, mutect2, varscan2
- MUC17 | c.4552A>G p.S1518G | Missense Mutation (SNP) | VAF 85/416 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs771440942, COSV60291806; called by muse, mutect2, varscan2
- NFIA | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 74/378 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV63608795; called by muse, mutect2, varscan2
- NSMAF | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs35436008, COSV50689328; called by muse, mutect2, varscan2
- NTF3 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 51/212 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs1408813478, COSV58417724; called by muse, mutect2, varscan2
- OR1E2 | c.335G>A p.S112N | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV50265776; called by muse, mutect2, varscan2
- P3H3 | c.1762T>A p.C588S | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782522423, COSV51834024; called by muse, mutect2, varscan2
- PAPPA2 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774370341, COSV62779980; called by muse, mutect2, varscan2
- PCDHA1 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 14/227 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65374900, COSV65377245; called by muse, mutect2
- PCNX1 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 61/191 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as rs761689971, COSV53096289, COSV53096295; called by muse, mutect2, varscan2
- PEX19 | c.614G>A p.S205N | Missense Mutation (SNP) | VAF 121/407 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.043); catalogued as COSV100926947, COSV63619703; called by muse, mutect2, varscan2
- PPARG | c.668C>T p.A223V (on ENST00000287820 / NM_015869.5; = p.A193V on NM_005037.7) | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as rs573789959, COSV55142519; called by muse, mutect2, varscan2
- PTCHD1 | c.416T>C p.I139T | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV65061171; called by muse, mutect2, varscan2
- RMDN3 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV53024382; called by muse, mutect2, varscan2
- RTL3 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs369311059, COSV58183086; called by muse, mutect2, varscan2
- SNX9 | c.1432G>T p.V478L | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.524); catalogued as COSV67584712; called by muse, mutect2, varscan2
- SP7 | c.1145G>C p.G382A | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.045); catalogued as COSV100382050, COSV58191127; called by muse, mutect2, varscan2
- SPINT1 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 78/261 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs145193299; called by muse, mutect2, varscan2
- SPTA1 | c.4003C>T p.R1335C | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs758705311, COSV63754837, COSV63760532; called by muse, mutect2, varscan2
- ST18 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs1426720360, COSV52497335; called by muse, mutect2, varscan2
- STK31 | c.2597A>G p.E866G | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV63456962; called by muse, mutect2, varscan2
- SUCNR1 | c.128T>C p.I43T | Missense Mutation (SNP) | VAF 177/580 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV62912367; called by muse, mutect2, varscan2
- TTN | c.97311_97314del p.R32438Sfs*9 (on ENST00000591111; = p.R25014Sfs*9 on NM_003319.4) | Frame Shift Del (DEL) | VAF 33/155 reads (21%) | catalogued as rs754731686; called by mutect2, pindel, varscan2
- TTN | c.32780C>T p.P10927L (on ENST00000591111; = p.P10000L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/129 reads (27%) | PolyPhen benign (0.009); catalogued as rs760545521, COSV59864966, COSV60085696; called by muse, mutect2, varscan2
- VEGFD | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs766709138, COSV52910001; called by muse, mutect2, varscan2
- XIRP2 | c.9386G>A p.R3129H (on ENST00000628543; = p.R3304H on NM_152381.6) | Missense Mutation (SNP) | VAF 87/286 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as rs762492641, COSV54708355; called by muse, mutect2, varscan2
- ZNF451 | c.137T>C p.I46T | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62598087; called by muse, mutect2, varscan2
- ADAMTS2 | c.1323C>T p.A441= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs781602081, COSV51083357; called by muse, mutect2, varscan2
- CCT8L2 | c.900C>T p.D300= | Silent (SNP) | VAF 126/332 reads (38%) | catalogued as rs772533950, COSV63462162; called by muse, mutect2, varscan2
- FSCB | c.1095T>C p.A365= | Silent (SNP) | VAF 90/300 reads (30%) | catalogued as COSV61218454; called by muse, mutect2, varscan2
- IL10 | c.498C>T p.N166= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV65594651; called by muse, mutect2, varscan2
- KCNU1 | c.2472C>T p.I824= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as rs368687816; called by muse, mutect2, varscan2
- KRT13 | c.369C>T p.R123= | Silent (SNP) | VAF 68/208 reads (33%) | catalogued as rs746913289, COSV55840279; called by muse, mutect2, varscan2
- KSR2 | c.1593G>A p.S531= | Silent (SNP) | VAF 39/142 reads (27%) | catalogued as rs762371454, COSV56675038; called by muse, mutect2, varscan2
- OR5M10 | c.672G>A p.A224= | Silent (SNP) | VAF 36/145 reads (25%) | catalogued as rs772311852, COSV73242348; called by muse, mutect2, varscan2
- PAGE1 | c.207A>G p.P69= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV65998191; called by muse, mutect2, varscan2
- PBXIP1 | c.1408A>C p.R470= | Silent (SNP) | VAF 203/685 reads (30%) | catalogued as COSV63777316; called by muse, mutect2, varscan2
- PLXDC1 | c.213C>A p.T71= | Silent (SNP) | VAF 25/111 reads (23%) | catalogued as rs371702899, COSV59551711; called by muse, mutect2, varscan2
- PSD4 | c.246C>T p.D82= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs147089589; called by muse, mutect2, varscan2
- RBFOX1 | c.348C>A p.P116= | Silent (SNP) | VAF 8/173 reads (5%) | catalogued as COSV100301851; called by muse, mutect2
- RNF113A | c.318G>A p.A106= | Silent (SNP) | VAF 214/686 reads (31%) | catalogued as rs1329989457, COSV65097493; called by muse, mutect2, varscan2
- SALL4 | c.1035G>A p.Q345= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV53853208, COSV99409177; called by muse, mutect2, varscan2
- SIM1 | c.750G>A p.A250= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV53493243, COSV53496487; called by muse, mutect2, varscan2
- SLC45A4 | c.372C>T p.L124= (on ENST00000517878 / NM_001286646.2; = p.L73= on NM_001080431.2) | Silent (SNP) | VAF 53/189 reads (28%) | catalogued as COSV50142290; called by muse, mutect2, varscan2
- SLCO5A1 | c.636C>T p.F212= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs1444328899, COSV52661345; called by muse, mutect2, varscan2
- SLITRK2 | c.822G>A p.R274= | Silent (SNP) | VAF 73/270 reads (27%) | catalogued as rs781845889, COSV100158197, COSV59423320, COSV59427135; called by muse, mutect2, varscan2
- SV2C | c.435C>T p.C145= | Silent (SNP) | VAF 64/232 reads (28%) | catalogued as rs745535885, COSV59221938; called by muse, mutect2, varscan2
- TLK2 | c.1851G>A p.S617= (on ENST00000326270 / NM_001284333.2; = p.S595= on NM_006852.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 38/154 reads (25%) | catalogued as rs751158242, COSV58301494; called by muse, mutect2, varscan2
- TP53BP1 | c.1971G>A p.E657= | Silent (SNP) | VAF 86/289 reads (30%) | catalogued as COSV55503172; called by muse, mutect2, varscan2
- ZNF780A | c.1731A>G p.K577= | Silent (SNP) | VAF 98/341 reads (29%) | catalogued as rs779961382, COSV61814475, COSV61815645; called by muse, mutect2, varscan2
- SLC22A17 | n.700C>T | RNA (SNP) | VAF 30/93 reads (32%) | catalogued as COSV52835980; called by muse, mutect2, varscan2
